Somatic mutation profile of tumor specimen TCGA-D8-A1XR-01A (aliquot TCGA-D8-A1XR-01A-11D-A14K-09) from TCGA case TCGA-D8-A1XR, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 56.1 years (20,488 days).
Specimen TCGA-D8-A1XR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3ff80d9-515c-48b3-950e-30851d821670.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1XR-10A (Blood Derived Normal), aliquot TCGA-D8-A1XR-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f93cb4a-be70-445f-a52e-b75edc186d0c

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 3, RNA 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BSN | c.7300C>T p.R2434C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768251009, COSV56529194; called by muse, mutect2, varscan2
- CIT | c.3985G>A p.A1329T | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55885294; called by muse, mutect2, varscan2
- DENND2D | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62960291; called by muse, mutect2, varscan2
- DIP2A | c.2386A>T p.I796F | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV59488164; called by muse, mutect2, varscan2
- DSCAM | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1432629129, COSV68648785; called by muse, mutect2, varscan2
- ETV3L | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV71901227; called by muse, mutect2, varscan2
- FBXO7 | c.997G>C p.V333L | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV56681864; called by muse, mutect2, varscan2
- JADE3 | c.974G>A p.C325Y | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54470845; called by muse, mutect2, varscan2
- MAP2K3 | c.545G>A p.S182N (on ENST00000342679 / NM_145109.3; = p.S153N on NM_002756.4) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV57578877; called by muse, mutect2, varscan2
- P2RY10 | c.272T>A p.I91N | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50687575; called by muse, mutect2, varscan2
- PEG3 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as rs549894601, COSV55649159, COSV55649708; called by muse, mutect2, varscan2
- PHF24 | c.967T>C p.W323R | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54277294; called by muse, mutect2, varscan2
- QSER1 | c.1208C>T p.S403F (on ENST00000399302; = p.S532F on NM_001076786.3) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV67901943; called by muse, mutect2, varscan2
- SH3KBP1 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs776375600, COSV65650344; called by muse, mutect2, varscan2
- SMC3 | c.2701A>G p.M901V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV62422719; called by muse, mutect2, varscan2
- STAG3 | c.331A>T p.M111L | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100425934; called by muse, mutect2
- TAFA5 | c.184G>A p.A62T (on ENST00000402357 / NM_001082967.3; = p.A55T on NM_015381.7) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs777360580, COSV60970759; called by mutect2, varscan2
- TPM3 | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV55139751; called by muse, mutect2, varscan2
- ZNF714 | c.278T>A p.V93D | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52516189; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.162dup p.Y55Ifs*2 | Frame Shift Ins (INS) | VAF 26/80 reads (33%) | called by mutect2, pindel, varscan2
- FOXA1 | c.1171_1191del p.D391_N397del | In Frame Del (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- CUL4A | c.1146G>A p.K382= (on ENST00000375440 / NM_001008895.4; = p.K282= on NM_003589.3) | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs971211908, COSV58376574; called by muse, mutect2, varscan2
- ERICH6 | c.117A>G p.E39= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs867015960, COSV55801665; called by muse, mutect2, varscan2
- MRPL27 | c.117C>T p.S39= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs1301065287, COSV56813412; called by muse, mutect2, varscan2
- FAM74A3 | n.69C>A | RNA (SNP) | VAF 60/194 reads (31%) | catalogued as rs112785686; called by muse, mutect2, varscan2
